Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABPA, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABPA-TTP1-A (FFPE Scrolls).

[page 1 of 7]
Results

SURGICAL CASE RESULT (Order [REDACTED])

Patient InformationSex
FemaleDOB
[REDACTED]**Collection Information**

Collected [REDACTED] +0

Resulting Agency: [REDACTED]

Result Date - [REDACTED] +19

Component Results**Component****Text**

**** THIS IS AN ADDENDUM REPORT ****

CASE: [REDACTED]

PATIENT [REDACTED]

Nature of Specimen:

- A. Right Ovary, Resection
- B. Right Pelvic Mass, Biopsy
- C. Uterus
- D. Left Ovary and Fallopian Tube, Resection
- E. Omentum, Omentectomy
- F. Small Bowel Mesentery Nodule
- G. Peritoneal Nodule
- H. Appendix
- I. Pelvic Tumor, Biopsy
- J. Small Bowel Mesentery
- K. Right Pelvic Lymph Node, Biopsy
- L. Right Periaortic Lymph Node, Biopsy
- Pre-Op Diagnosis: Pelvic mass
- Post-Op Diagnosis: None given
- Clinical History: None given
- Copies of report to: None requested

FINAL DIAGNOSIS:

- A) Right ovary and fallopian tube, salpingo-oophorectomy:
- Small cell carcinoma. See Comment.
- Fallopian tube showing paratubal cysts; negative for malignancy.
- B) Right pelvic mass, resection:
- Metastatic small cell carcinoma.
- C) Uterus and cervix, hysterectomy:
- Basal and proliferative endometrium.
- Intramural uterine leiomyoma.
- Mild chronic cervicitis.
- No evidence of malignancy
- D) Left ovary and fallopian tube, salpingo-oophorectomy:
- Multiple ovarian follicle cysts.
- Fallopian tube showing no diagnostic abnormality.
- No evidence of malignancy.
- E) Omentum, omentectomy:
- Metastatic small cell carcinoma.
- F) Small bowel mesentery, biopsy:
- Metastatic small cell carcinoma.
- G) Peritoneal nodule, resection:
- Metastatic small cell carcinoma.
- H) Vermiform appendix, appendectomy:
- Fibroadipose obliteration of appendiceal lumen.
- Serosal implants of metastatic small cell carcinoma with associated inflammation and reactive mesothelial proliferation.

[page 2 of 7]
- I) Pelvic mass, resection:
- Metastatic small cell carcinoma.
- J) Small bowel mesentery, biopsy:
- Metastatic small cell carcinoma.
- K) Right pelvic lymph node dissection:
- Fourteen lymph nodes identified, all negative for malignancy (0/14).
- L) Right periaortic lymph node dissection:
- Twelve lymph nodes identified, all negative for malignancy (0/12).

COMMENT: Immunostains, all with appropriate positive controls, show staining of scattered tumor cells for EMA, CA-125 and occasional slight pan-cytokeratin staining. The tumor is negative for inhibin and CD99, and has no features of a granulosa cell or other sex cord-stromal tumor as initially favored on frozen section. Neuron-specific enolase has nonspecific staining. Chromogranin is negative, arguing against a small cell carcinoma of pulmonary type. The tumor is essentially patternless and is composed mainly of small cells, with a minor component of cells showing similar nuclei and more abundant cytoplasm. Mitotic activity is brisk. Clinically, the patient has a mildly elevated serum calcium level. This finding, together with the tumor morphology and undifferentiated nature, is consistent with a small cell carcinoma of hypercalcemic type showing areas of large cell morphology. [REDACTED] has reviewed this case and concurs with the diagnosis.

OVARIAN CARCINOMA CASE SUMMARY:

Specimen type: Left and right salpingo-oophorectomy, hysterectomy, omentectomy, peritoneal biopsies.

Tumor (microscopic):

Histologic type: Small cell carcinoma, hypercalcemic type.
Degree of malignancy: Carcinoma
Grade: Poorly differentiated

Tumor extent:

Primary site of involvement: Right ovary
Ovaries involved: Right
Surface growth: None
Parenchymal growth: Right
Capsule: Left: Intact, Right: Intact
Greatest tumor dimension: Right ovary: 21.5 cm
Pelvic extension/implants:
Uterus: No
Fallopian tube: No
Other pelvic tissues: Pelvis: Peritoneal implants.
Extra-pelvic peritoneal metastasis: Yes, small bowel mesentery; appendiceal serosa.

Size: >2 cm.

Peritoneal implant type: Invasive

Ascites/peritoneal washing cytology: Negative, [REDACTED]

Summary of organs involved: One ovary, pelvic peritoneum, extrapelvic peritoneum, omentum.

Regional lymph nodes: 0 involved/26 examined.

Distant metastasis: Not assessed.

Stage: 3C (pT 3c, pN 0, pM X)

Staging based on:

AJCC Cancer Staging Manual, Sixth Edition

Greene, FL, et al, eds., Springer-Verlag, 2002.

GROSS:

The specimen is received fresh for frozen section labeled "right ovary", and consists of a 1515 gram ovary measuring 21.5 x 16.0 x 10.5 cm with an attached 5.5 cm long by 0.7 cm diameter fallopian tube. The outer surface of the ovary is intact and tan-white. On

[page 3 of 7]
cut section, there is no normal appearing ovary present. The ovary is entirely replaced with a solid, white-tan mass with areas of cystic degeneration and hemorrhage. A representative section of the mass is submitted for frozen section and the remnants are resubmitted in cassette [REDACTED]. The fallopian tube has a smooth, glistening, pink-red outer surface and is unremarkable. A representative section is submitted as follows: Cassette A2 through A19 - ovarian mass, A20 - fallopian tube.

The specimen is received fresh labeled "right pelvic mass", and consists of two fragments of soft tissue. The first fragment of tissue measuring 3.8 x 2.6 x 1.7 cm and consists of yellow adipose tissue, hemorrhage, and soft pink tissue. The second piece measures 4.7 x 2.6 x 1.2 cm and consists of a friable, soft, pink-white mass. There are no recognizable anatomic structures. Representative sections are submitted as follows: Cassette B1 and B2 representative sections of the primarily fatty piece, B3 and B4 representative sections of the friable pink-white tissue.

+0

The specimen is received fresh for gross examination labeled "uterus" and consists of a 52.0 gram uterus measuring 8.0 cm from superior to inferior by 4.5 cm from cornu to cornu by 2.5 cm from anterior to posterior. The outer surface of the uterus is pink-red, smooth and glistening. There are no tumor implants on the outer surface of the uterus. The endometrium is lined with a glistening, tan-pink mucosa and is 0.1 cm thick. There is a 1.6 x 1.5 x 1.5 cm well circumscribed, firm, white-tan, whorled nodule located within the myometrium at the fundus. There are no areas of hemorrhage or necrosis within the mass. The exocervix measures 2.3 cm in diameter and has a 0.7 cm slit-like external os. The exocervix is lined with an unremarkable, white, glistening mucosa. The endocervix is lined with a tan-pink, herringbone mucosa. Representative sections are submitted in cassettes as follows: Cassette C1 - posterior endometrium; C2 - anterior endometrium; C3 - posterior cervix; C4 anterior cervix; C5 - tan-white whorled nodule.

+1

The specimen is received in formalin labeled "left tube and ovary" and consists of a 10 gram ovary and fallopian tube. The ovary measures 2.8 x 2.0 x 1.5 cm and is cystically dilated. The fallopian tube measures 4.9 x 0.9 cm in diameter. The outer surface of the ovary is smooth and white-pink. The lining of the cyst wall are smooth and pink-tan. No tumor implants are identified. The outer surface of the fallopian tube is pink-red, smooth, and glistening. The ovary is entirely submitted and representative sections of the fallopian tube are submitted as follows: B1 through B3 - ovary, B4 - fallopian tube.

+1

The specimen is received fresh labeled "omentum", and consists of seven pieces of tan-yellow lobulated, vascular omental tissue. The pieces range from 2.5 cm to 2.0 cm in greatest dimension 25.0 x 16.0 x 0.8 cm in aggregate. There are approximately four tan-pink rubbery, bosselated firm tumor implants on the omental surface ranging from 0.3 cm to 2.0 cm in greatest dimensions. Representative sections of the omentum and tumor implants are submitted in cassettes E1 and E2.

The specimen is received fresh labeled "small bowel mesenteric nodule", and consists of a portion of tan-pink membranous to tan-yellow fatty tissue measuring 1.0 x 1.0 x 0.5 cm in overall dimensions. There is a small tan-white rubbery nodule within the tissue measuring 0.5 x 0.4 x 0.3 cm. The specimen is submitted entirely in cassette F.

The specimen is received in formalin labeled "peritoneal nodule", and consists of a pink-red-maroon hemorrhagic glistening portion of tissue measuring 4.5 x 2.0 x 0.5 cm. On sectioning the tissue is

[page 4 of 7]
red-maroon and hemorrhagic. The specimen is submitted entirely in cassette G1 and G2.

The specimen is received fresh labeled "appendix", and consists of an intact tan-pink vermiform appendix measuring 6.0 cm in length by 0.6 cm in external diameter. Periapendiceal adipose tissue which tan-yellow to red travels along the length of the appendix measuring 7.0 x 3.0 x 0.5 cm. The adipose tissue at the tip of the appendix is hemorrhagic, dusky and demonstrates white-tan fibrinopurulent exudate. On sectioning the lumen is unremarkable with no lesions, fecalith or areas of perforation identified. On sectioning the periappendiceal adipose tissue at the tip of the appendix reveals tan-yellow lobulated glistening tissue with the hemorrhage and exudate on the outer surface. Representative sections are submitted in cassettes H1 through H3 including the bivalve tip in cassette H2 and the adipose tissue at the tips of the appendix in H3.

The specimen is received fresh labeled "pelvic tumor" and consists of an 18.3 x 10.8 x 3.1 cm portion of fragmented soft tissue. The majority of the tissue is comprised of soft white-pink tissue with areas of hemorrhage. There are no identifiable anatomic land marks. Representative sections are submitted in cassettes I1 through I4.

+0

The specimen is received fresh labeled "small bowel mesentery", and consists of two portions of tissue measuring 3.3 x 3.3 x 0.6 cm and 3.5 x 2.5 x 0.5 cm. The specimen is comprised predominately of soft pink-white tissue and yellow-orange adipose tissue with a small amount of hemorrhage. Representative sections are submitted in cassettes J1 and J2.

The specimen is received fresh labeled "right pelvic lymph nodes", and consists of three pieces of adipose tissue ranging in size from 3.0 cm to 1.9 cm in greatest dimension. Within the yellow-orange adipose tissue are 8 possible pink-red lymph nodes. The entire specimen is submitted as follows: K1-two lymph nodes, K2-4 lymph nodes, K3-2 lymph nodes, K4-adipose tissue, K5-adipose tissue. The specimen is received fresh labeled "right periaortic lymph node", and consists of two portions of adipose tissue measuring 4.2 x 2.5 x 0.6 cm and 1.4 x 1.1 x 0.8 cm. No lymphoid tissue is identified. The specimen is submitted entirely in cassette L1 and L2.

+0

FROZEN SECTION EXAMINATION:

AFS) Right ovary:

- Favor sex-cord stromal tumor.

CFS) Uterus, hysterectomy (gross examination only):

- No gross evidence of malignancy.
- Intramural leiomyoma.

MICROSCOPIC:

Microscopic examination was performed. See diagnosis.

+3

+3

The immunohistochemical tests reported were developed and performance characteristics determined by

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests may be used for clinical purposes. They should not be regarded as investigational or for research use only.

is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Pathologist

Electronically signed +4

THIS IS AN ADDENDUM REPORT ISSUED:

[page 5 of 7]
At the request of the clinician, this case was sent to [REDACTED] Laboratories for evaluation by fluorescence in-situ hybridization (FISH) for the presence of a translocation involving the EWSR gene. Their report reads as follows:

Negative for a translocation involving the EWSR gene by fluorescence in-situ hybridization.

COMMENT: The absence of a detectable translocation involving the EWSR gene by FISH argues strongly against involvement by primitive neuroectodermal tumor (PNET/Ewing sarcoma).

See their separate complete report.

+19

Electronically signed [REDACTED] +19

Pathologist

Electronically signed [REDACTED] +19

Lab and Collection

SURGICAL CASE RESULT on [REDACTED] +0

Result History

SURGICAL CASE RESULT on [REDACTED] +19

+19

Result Information

Status

Edited [REDACTED] +19

Provider Status

Reviewed

Patient Release Status:

This result is not viewable by the patient.

Order

SURGICAL CASE RESULT [REDACTED] (Order [REDACTED])

Patient Information

Patient Name

Sex

Female

DOB

Result Information

Status

Edited [REDACTED] +19

Provider Status: Reviewed

Order Information

Order Date/Time

+0

Release Date/Time

None

Start Date/Time

End Date/Time

None

Provider Information

Ordering User

Interface, Results One

Authorizing Provider:

Attending Provider(s):

Admitting Provider:

PCP:

Order Information

Date

+0

Department

Ordering

Interface,

Results One

Authorizing

Reprint Order Requisition

SURGICAL CASE RESULT [REDACTED] on [REDACTED] +0

Detailed Information

Priority and Order Details

Collection Information

[page 6 of 7]
Results

CT ABDOMEN AND PELVIS WITH CONTRAST (Order [REDACTED])

Patient Information

[REDACTED]	Sex Female	DOB [REDACTED]
Lab [REDACTED]	PACS Report Click here for detailed report or images for CT ABDOMEN AND PELVIS WITH CONTRAST	
Resulting Physician [REDACTED]		

+2782

Interface, Results One**Result Narrative**

789.01.

Helical scans of the abdomen and pelvis were obtained following the intravenous administration of contrast material. Sagittal and coronal reformatted images were evaluated as well. Comparison is made with the prior examination of [REDACTED] +1154

Postsurgical changes from a hysterectomy, bilateral salpingo-oophorectomy, greater omentectomy and lymph node dissection are noted.

There is pelvic floor relaxation associated with a cystocele and sigmoidocele.

There is disc diffuse mural thickening of the colon most marked involving the cecum and ascending colon. This is associated with submucosal edema and engorgement of the vasa recta. Minimal thickening of the terminal ileum is identified as well. No splanchnic vascular thrombosis is noted. No pneumatosis, mesenteric or portal venous gas are identified.

The appendix is not specifically identified however no secondary signs of appendicitis are present. An increased number of normal size mesenteric lymph nodes are identified. This is of uncertain clinical significance and may relate to the patient's colitis.

There is diffuse hepatic steatosis. Several cystic lesions are once again seen within the liver. These have remained relatively stable since the study of [REDACTED] ~+1029

No focal splenic, adrenal, or renal masses are noted.

There is a small cystic lesion identified within the pancreatic body. It measures 7.8 mm in diameter. [REDACTED] it measured 5.4 mm in diameter.

~+1029

Multilevel degenerative disease is seen in the spine.

There is nonobstructive small bowel adhesive disease along the anterior abdominal wall.

There is a trace amount of free fluid seen in the pelvis. It has a density of 25 Hounsfield units.

Impression:

1. Diffuse mural thickening of the colon is identified suspicious for an infectious, inflammatory, or less likely ischemic colitis.

[page 7 of 7]
~+1029

2. There is a cystic lesion seen in the pancreatic body which measures 7.8 mm in diameter. In [REDACTED] it measured 5.4 mm in diameter. Further evaluation with MR and MRCP of the cystic pancreatic lesion is recommended. This could be performed after the patient's colitis resolves. There is nonobstructive small bowel adhesive disease seen along the anterior abdominal wall.

3. There is a trace amount of free fluid seen in the pelvis. This may relate to the patient's colitis. In this patient with a history of multiple gynecologic malignancy follow-up imaging is recommended to a short resolution. No other CT stigmata of recurrent disease are noted.

4. Hepatic steatosis associated with multiple hepatic cysts.

This exam was dictated at [REDACTED]

FINAL REPORT

Thank you for referring your patient [REDACTED]

Dictated on: [REDACTED] +2782

Dictating Resident/Fellow/Attending Radiologist: [REDACTED]
MD

Transcribed by: [REDACTED] +2782

Electronically Verified and Signed by Attending Radiologist: [REDACTED]

[REDACTED] +2782

Lab and Collection

+2782

CT ABDOMEN AND PELVIS WITH CONTRAST (Order [REDACTED])

Lab and Collection Information

Result History

+2782

CT ABDOMEN AND PELVIS WITH CONTRAST (Order [REDACTED])

Order Result History Report

Result Information

Status

Provider Status

Final result [REDACTED]

Ordered

Patient Release Status: +2782

This result is viewable by the patient in [REDACTED]

Order

CT ABDOMEN AND PELVIS WITH CONTRAST [REDACTED]

Patient Information

Patient Name [REDACTED]

Sex

DOB [REDACTED]

Female

Result Information

Status

Final result [REDACTED]

+2782

Provider Status: Ordered

Order Information

Order Date/Time [REDACTED]

Release Date/Time [REDACTED]

Start Date/Time [REDACTED]

End Date/Time [REDACTED]

+2782

+2782

+2782

+2782

Provider Information

Order Information

Source: NCI Genomic Data Commons file 647b2574-8096-4aa1-927a-76ffdd8833c5 (ER0122 ER-ABPA Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).